Somatic mutation profile of tumor specimen 0DT20Z from CCDI case PBCISE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ganglioneuroma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.5 years (6,015 days).
Specimen 0DT20Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22302771-2ffd-4db7-baa1-55ada701e935.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT20K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8d9b10f-08c3-41a2-9c67-1a237899427c

The open-access MAF lists 25 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, Intron 4, 3'UTR 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AARS1 | c.1019A>G p.N340S | Missense Mutation (SNP) | VAF 236/617 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.417); catalogued as rs140135726; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPRASP2 | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 571/726 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1303096785; called by muse, mutect2, varscan2
- IL17A | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 377/896 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780929803, COSV60684362; called by muse, mutect2, varscan2
- LAMC3 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 107/863 reads (12%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.612); catalogued as COSV63093410; called by muse, mutect2, varscan2
- MANEAL | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 46/306 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs1248706977; called by muse, mutect2, varscan2
- AGO1 | c.1812del p.K606Nfs*8 | Frame Shift Del (DEL) | VAF 174/620 reads (28%) | called by mutect2, pindel, varscan2
- ATRX | c.4506G>C p.E1502D | Missense Mutation (SNP) | VAF 302/860 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.187); called by muse, varscan2
- ECHDC2 | c.466G>A p.A156T (on ENST00000371522 / NM_001198961.2; = p.A125T on NM_018281.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 169/254 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- JAG2 | c.2602T>C p.F868L | Missense Mutation (SNP) | VAF 118/290 reads (41%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NCDN | c.1945C>T p.P649S | Missense Mutation (SNP) | VAF 182/507 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- NCDN | c.1946C>T p.P649L | Missense Mutation (SNP) | VAF 180/520 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- TBX3 | c.1877A>G p.H626R (on ENST00000257566 / NM_016569.4; = p.H606R on NM_005996.4) | Missense Mutation (SNP) | VAF 213/474 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ZNF195 | c.1649A>G p.Y550C (on ENST00000399602 / NM_001130520.3; = p.Y478C on NM_007152.5) | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- OCM | c.147G>C p.R49= | Silent (SNP) | VAF 426/1122 reads (38%) | called by muse, mutect2, varscan2
- OR10P1 | c.648C>T p.V216= | Silent (SNP) | VAF 34/804 reads (4%) | called by muse, mutect2
- PIK3CD | c.1719G>A p.E573= | Silent (SNP) | VAF 147/406 reads (36%) | catalogued as rs774421473; called by muse, mutect2, varscan2
- PTOV1 | c.1056C>T p.H352= | Silent (SNP) | VAF 95/499 reads (19%) | called by muse, mutect2, varscan2
- RIF1 | c.3627A>G p.G1209= | Silent (SNP) | VAF 229/1490 reads (15%) | called by muse, mutect2, varscan2
- ATRX | c.4557+90G>A | Intron (SNP) | VAF 22/88 reads (25%) | called by muse, varscan2
- GDF11 | c.*12G>A | 3'UTR (SNP) | VAF 32/552 reads (6%) | called by muse, mutect2
- KRTAP19-6 | c.*59C>T | 3'UTR (SNP) | VAF 268/647 reads (41%) | catalogued as rs763913664, COSV61843797, COSV61843857; called by muse, mutect2, varscan2
- PDLIM5 | c.920+656C>G | Intron (SNP) | VAF 304/796 reads (38%) | called by mutect2, varscan2
- RRP8 | c.917+42C>T | Intron (SNP) | VAF 88/393 reads (22%) | called by muse, mutect2, varscan2
- TMF1 | c.2244+43G>T | Intron (SNP) | VAF 68/564 reads (12%) | called by muse, mutect2
- TRIM49 | c.*70T>G | 3'UTR (SNP) | VAF 70/394 reads (18%) | called by muse, varscan2
